Somatic mutation profile of tumor specimen 0DRSTY from CCDI case PBCGDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 14.5 years (5,285 days).
Specimen 0DRSTY: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 091f4742-7002-4a39-9c68-98b794dc1cde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRSSA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27498252-824d-47ce-a5a4-9eca9d7284df

The open-access MAF lists 128 somatic variants for this specimen: 72 protein-altering or splice-affecting, 32 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 32, Intron 10, 3'UTR 8, 5'UTR 6, Nonsense Mutation 4, Frame Shift Ins 4, Splice Site 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASPA | c.244dup p.M82Nfs*8 | Frame Shift Ins (INS) | VAF 62/284 reads (22%) | catalogued as rs756198538; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 113/425 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- APOB | c.3595G>A p.D1199N | Missense Mutation (SNP) | VAF 61/345 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs375894411; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ARHGAP32 | c.3562G>A p.G1188R (on ENST00000310343 / NM_001378025.1; = p.G839R on NM_014715.4) | Missense Mutation (SNP) | VAF 129/365 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs746664458; called by muse, mutect2, varscan2
- ARID3A | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs760005633; called by muse, mutect2, varscan2
- BDH1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.78); catalogued as rs772452248, COSV64017981; called by muse, varscan2
- BLVRA | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs753216810; called by muse, mutect2, varscan2
- C9orf131 | c.3163C>T p.L1055F | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV56612077; called by muse, mutect2, varscan2
- CFAP74 | c.1878C>A p.D626E | Missense Mutation (SNP) | VAF 93/460 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs749073124; called by muse, mutect2, varscan2
- COL11A2 | c.3480G>T p.L1160F (on ENST00000341947 / NM_080680.3; = p.L1053F on NM_080679.2) | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs927537693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA1 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 85/352 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs540697892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- EFL1 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 75/299 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745873091, COSV51604792; called by muse, mutect2, varscan2
- EXOSC9 | c.311G>C p.R104P | Missense Mutation (SNP) | VAF 80/439 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54665619, COSV54666922; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1562G>C p.R521P | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV100362183; called by muse, mutect2
- HCCS | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV58238791; called by muse, mutect2, varscan2
- INF2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53029290; called by muse, mutect2, varscan2
- ITGB2 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 99/459 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs778870549; called by muse, mutect2, varscan2
- LGR5 | c.1752A>T p.R584S | Missense Mutation (SNP) | VAF 74/526 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs142182177; called by muse, mutect2, varscan2
- LRP2 | c.10145C>A p.A3382E | Missense Mutation (SNP) | VAF 76/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55543041, COSV55552382; called by muse, mutect2, varscan2
- LRRIQ1 | c.4040G>T p.R1347L | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748238601, COSV101279732; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs993537549; called by muse, mutect2, varscan2
- MYO15A | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52759937; called by muse, mutect2, varscan2
- NCOA3 | c.1473G>C p.K491N | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV59065557; called by muse, mutect2, varscan2
- OR4C15 | c.481G>T p.A161S (on ENST00000314644; = p.A107S on NM_001001920.2) | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.911); catalogued as COSV58951148; called by muse, mutect2, varscan2
- OR4P4 | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58923385; called by muse, mutect2, varscan2
- TAP1 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 107/513 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769612391; called by muse, mutect2
- TG | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 88/900 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs750438327; called by muse, mutect2
- TNFRSF11B | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 67/641 reads (10%) | catalogued as COSV52074983; called by muse, mutect2, varscan2
- TSHZ2 | c.3023C>T p.A1008V | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754153089, COSV61588018; called by muse, mutect2, varscan2
- ADAM7 | c.2254A>G p.S752G | Missense Mutation (SNP) | VAF 62/681 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- ADGRB1 | c.3399G>A p.G1133= | Splice Region (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2
- ARHGAP39 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10D | c.1904G>T p.R635L | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BCOR | c.4064_4068dup p.P1357Rfs*14 (on ENST00000378444 / NM_001123385.2; = p.P1323Rfs*14 on NM_017745.6) | Frame Shift Ins (INS) | VAF 165/190 reads (87%) | called by mutect2, pindel, varscan2
- BNIP5 | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD18 | c.267G>T p.L89F | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CCDC57 | c.2297C>T p.P766L | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CCDC91 | c.586A>C p.K196Q | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEMIP | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CFAP65 | c.4954G>T p.E1652* | Nonsense Mutation (SNP) | VAF 81/463 reads (17%) | called by muse, mutect2, varscan2
- CORIN | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 85/412 reads (21%) | called by muse, mutect2, varscan2
- CPNE9 | c.377+2T>G p.X126_splice | Splice Site (SNP) | VAF 48/218 reads (22%) | called by muse, mutect2, varscan2
- CYP3A7 | c.1416+1G>A p.X472_splice | Splice Site (SNP) | VAF 85/540 reads (16%) | called by muse, mutect2, varscan2
- DNAH3 | c.8897G>T p.R2966M | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELOVL2 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- FRYL | c.8341G>T p.E2781* | Nonsense Mutation (SNP) | VAF 148/371 reads (40%) | called by muse, mutect2, varscan2
- GABRA2 | c.423G>C p.M141I | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2
- GAD2 | c.1219C>A p.L407I | Missense Mutation (SNP) | VAF 80/363 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GIT2 | c.1981G>T p.A661S (on ENST00000355312 / NM_057169.5; = p.A583S on NM_014776.5) | Missense Mutation (SNP) | VAF 144/540 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HMX3 | c.164_170dup p.P58Lfs*42 | Frame Shift Ins (INS) | VAF 39/196 reads (20%) | called by mutect2, varscan2
- KIT | c.2647A>G p.I883V | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MB21D2 | c.912C>A p.S304R | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MUC12 | c.1829C>G p.P610R (on ENST00000379442; = p.P467R on NM_001164462.1) | Missense Mutation (SNP) | VAF 82/1009 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2
- MUC3A | c.3692C>A p.A1231E | Missense Mutation (SNP) | VAF 66/472 reads (14%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MYO3A | c.3562A>C p.T1188P | Missense Mutation (SNP) | VAF 115/505 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NCAN | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 130/554 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OPLAH | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 91/721 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PNPLA4 | c.756T>G p.F252L | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRC2C | c.7048_7049del p.Q2350Dfs*120 (on ENST00000367742; = p.Q2348Dfs*120 on NM_015172.4) | Frame Shift Del (DEL) | VAF 340/809 reads (42%) | called by mutect2, pindel, varscan2
- RANBP10 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX7 | c.630G>C p.L210F (on ENST00000559447 / NM_001368074.1; = p.L307F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/347 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA5B | c.736dup p.E246Gfs*33 | Frame Shift Ins (INS) | VAF 102/433 reads (24%) | called by mutect2, pindel, varscan2
- SF3B3 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC15A2 | c.1727A>T p.D576V | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPHKAP | c.2809G>T p.V937F | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- STAB2 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 64/503 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAF3 | c.2373G>T p.R791S | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TEX14 | c.4235G>T p.R1412I (on ENST00000240361 / NM_001201457.2; = p.R1366I on NM_031272.5) | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX14 | c.1223G>C p.R408T (on ENST00000240361 / NM_001201457.2; = p.R402T on NM_031272.5) | Missense Mutation (SNP) | VAF 73/332 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- VNN1 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 87/379 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- XIRP1 | c.3101G>T p.G1034V | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ANKRD30A | c.2631A>G p.P877= (on ENST00000611781; = p.P821= on NM_052997.2) | Silent (SNP) | VAF 90/487 reads (18%) | called by muse, mutect2, varscan2
- ARF6 | c.114G>T p.S38= | Silent (SNP) | VAF 72/267 reads (27%) | called by mutect2, varscan2
- ASPM | c.6564G>A p.K2188= | Silent (SNP) | VAF 34/974 reads (3%) | called by muse, mutect2
- CAMK2D | c.477C>T p.G159= | Silent (SNP) | VAF 185/409 reads (45%) | called by muse, mutect2, varscan2
- CHD2 | c.1539A>T p.L513= | Silent (SNP) | VAF 80/266 reads (30%) | catalogued as COSV67713414; called by muse, mutect2, varscan2
- CLCN7 | c.45G>A p.R15= | Silent (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- COL8A2 | c.300A>T p.P100= | Silent (SNP) | VAF 32/194 reads (16%) | called by muse, mutect2, varscan2
- CRP | c.600T>C p.P200= | Silent (SNP) | VAF 11/397 reads (3%) | catalogued as COSV54814897; called by muse, mutect2
- DOCK4 | c.1095C>T p.H365= | Silent (SNP) | VAF 58/420 reads (14%) | catalogued as rs189759510, COSV70326782; ClinVar: likely benign; called by muse, mutect2, varscan2
- ENAM | c.240C>T p.N80= | Silent (SNP) | VAF 97/244 reads (40%) | catalogued as rs779873942; called by muse, mutect2, varscan2
- EPPK1 | c.8172G>T p.T2724= | Silent (SNP) | VAF 21/228 reads (9%) | called by muse, mutect2, varscan2
- GIMAP1 | c.612G>T p.L204= | Silent (SNP) | VAF 44/312 reads (14%) | called by muse, mutect2, varscan2
- INSL4 | c.333C>A p.R111= | Silent (SNP) | VAF 93/215 reads (43%) | called by muse, mutect2, varscan2
- KIF21A | c.2493G>A p.T831= (on ENST00000361418 / NM_001378440.1; = p.T818= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/311 reads (14%) | catalogued as rs961849577; called by muse, mutect2, varscan2
- OLIG2 | c.669G>A p.P223= | Silent (SNP) | VAF 70/274 reads (26%) | called by muse, mutect2, varscan2
- OR1A2 | c.216C>A p.I72= | Silent (SNP) | VAF 93/369 reads (25%) | called by muse, mutect2, varscan2
- PACSIN3 | c.402C>T p.D134= | Silent (SNP) | VAF 241/649 reads (37%) | catalogued as rs754617972; called by muse, mutect2, varscan2
- PFAS | c.1806C>T p.D602= | Silent (SNP) | VAF 69/290 reads (24%) | catalogued as rs766175984, COSV58981856; called by muse, mutect2, varscan2
- PLA2G4F | c.2073G>T p.L691= | Silent (SNP) | VAF 107/405 reads (26%) | called by muse, mutect2, varscan2
- POLR3A | c.2862G>A p.K954= | Silent (SNP) | VAF 82/438 reads (19%) | called by muse, mutect2, varscan2
- POTEC | c.111G>T p.G37= | Silent (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- PRR12 | c.483C>T p.P161= (on ENST00000615927; = p.P982= on NM_020719.3) | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs1448459843; called by muse, mutect2, varscan2
- RSPO3 | c.756G>A p.Q252= | Silent (SNP) | VAF 117/468 reads (25%) | called by muse, mutect2, varscan2
- SART1 | c.1635C>T p.P545= | Silent (SNP) | VAF 135/386 reads (35%) | catalogued as rs761112338; called by muse, mutect2, varscan2
- SLC19A3 | c.1329G>A p.G443= | Silent (SNP) | VAF 41/273 reads (15%) | catalogued as COSV51452881; called by muse, mutect2, varscan2
- SORCS3 | c.210G>A p.E70= | Silent (SNP) | VAF 108/409 reads (26%) | called by muse, mutect2, varscan2
- TASOR2 | c.4983C>T p.S1661= | Silent (SNP) | VAF 69/343 reads (20%) | called by muse, mutect2, varscan2
- TRPC7 | c.123G>A p.T41= | Silent (SNP) | VAF 94/288 reads (33%) | called by muse, mutect2, varscan2
- ZBED9 | c.399G>A p.E133= | Silent (SNP) | VAF 53/266 reads (20%) | called by muse, mutect2, varscan2
- ZC3H11B | c.2091C>A p.A697= | Silent (SNP) | VAF 41/577 reads (7%) | called by muse, mutect2
- ZFP64 | c.1557G>A p.V519= | Silent (SNP) | VAF 55/303 reads (18%) | called by muse, mutect2, varscan2
- ZPBP | c.78C>T p.A26= | Silent (SNP) | VAF 74/460 reads (16%) | called by muse, mutect2, varscan2
- AC024598.1 | c.981+20148C>T | Intron (SNP) | VAF 98/454 reads (22%) | catalogued as rs750050399, COSV101238126; called by muse, mutect2, varscan2
- ADAMTS13 | c.-18G>A | 5'UTR (SNP) | VAF 45/122 reads (37%) | catalogued as rs782338252, COSV100747033; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3752G>A | 3'UTR (SNP) | VAF 71/512 reads (14%) | catalogued as rs781576296; called by muse, mutect2, varscan2
- C5orf51 | c.*70A>G | 3'UTR (SNP) | VAF 46/249 reads (18%) | called by muse, mutect2, varscan2
- CACNA1D | c.5749+66dup | Intron (INS) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- CAPZA3 | c.-54C>A | 5'UTR (SNP) | VAF 82/246 reads (33%) | called by muse, mutect2, varscan2
- CCDC85A | c.*27C>A | 3'UTR (SNP) | VAF 87/284 reads (31%) | called by muse, mutect2, varscan2
- EPHA7 | c.832+91A>G | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, varscan2
- GRK5 | c.*7C>T | 3'UTR (SNP) | VAF 68/224 reads (30%) | called by muse, mutect2, varscan2
- GSTM5 | c.361-17G>T | Intron (SNP) | VAF 51/244 reads (21%) | called by muse, mutect2, varscan2
- HMCN2 | c.14588-43C>G | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- KHSRP | c.1889-13G>A | Intron (SNP) | VAF 43/249 reads (17%) | catalogued as rs369987126; called by muse, mutect2, varscan2
- KRT3 | c.-69C>A | 5'UTR (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- KRT5 | c.-9C>G | 5'UTR (SNP) | VAF 62/495 reads (13%) | called by muse, mutect2, varscan2
- LAMA5 | c.10601-31del | Intron (DEL) | VAF 48/228 reads (21%) | catalogued as rs746325128; called by mutect2, varscan2
- PAGE5 | c.-75C>A | 5'UTR (SNP) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- PERP | c.*551C>A | 3'UTR (SNP) | VAF 42/207 reads (20%) | called by muse, mutect2, varscan2
- PRSS16 | c.-23G>C | 5'UTR (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2
- RABGGTA | c.900+40C>A | Intron (SNP) | VAF 42/142 reads (30%) | called by mutect2, varscan2
- RNF123 | c.2304+58G>T | Intron (SNP) | VAF 48/242 reads (20%) | called by muse, mutect2, varscan2
- RNF24 | c.*2311G>T | 3'UTR (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2
- SAMD14 | c.1099-78G>A | Intron (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- SERBP1 | c.*14G>A | 3'UTR (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- TLR2 | c.*63G>T | 3'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
